Somatic mutation profile of tumor specimen BA2454D (aliquot aq-BA2454D) from BEATAML1.0 case 2234, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.9 years (27,002 days).
Specimen BA2454D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db47d1c3-d418-4e8f-8b4c-cad24636a9b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2407D (Solid Tissue Normal), aliquot aq-BA2407D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a8c00e4-f58a-4c2d-8951-d562c8dd0b03

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Silent 2, Splice Site 2, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 83/168 reads (49%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDC42EP1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1352090598; called by muse, mutect2, varscan2
- DNAJC25 | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as rs1369343110; called by muse, mutect2, varscan2
- FCGBP | c.8390C>T p.P2797L | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs571794043; called by muse, mutect2, varscan2
- HID1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs766799178; called by muse, varscan2
- KCNH6 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs34685943, COSV59000410; called by muse, mutect2, varscan2
- PEAR1 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 112/222 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757661147, COSV99440391, COSV99442448; called by mutect2, varscan2
- TSHZ2 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.794); catalogued as rs201353411, CM142650, COSV61587217, COSV61587698; called by muse, mutect2, varscan2
- SLC2A4RG | c.966C>A p.C322* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- SPRED2 | c.439-2A>T p.X147_splice | Splice Site (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- STIMATE | c.427+1G>T p.X143_splice | Splice Site (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- ACTN2 | c.1806C>T p.V602= | Silent (SNP) | VAF 99/206 reads (48%) | called by muse, mutect2, varscan2
- CDON | c.1089C>T p.N363= | Silent (SNP) | VAF 143/318 reads (45%) | catalogued as rs141744145; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF3E | c.91-435A>G | Intron (SNP) | VAF 86/204 reads (42%) | called by muse, varscan2
- NOS1 | c.*6909C>T | 3'UTR (SNP) | VAF 38/84 reads (45%) | catalogued as rs1178508722; called by muse, varscan2
- NRXN3 | c.989-7465G>A | Intron (SNP) | VAF 42/92 reads (46%) | catalogued as rs781285730, COSV55339639; called by muse, varscan2
- RPL12 | c.38-58G>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
